Somatic mutation profile of tumor specimen ALCH-AF3T-TTP1-A (aliquot ALCH-AF3T-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-AF3T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.4 years (26,797 days).
Specimen ALCH-AF3T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb4f97dc-c65e-4d93-85b5-d7856fcc434d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF3T-NB1-A (Blood Derived Normal), aliquot ALCH-AF3T-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f9e3af7-c6cf-487b-b53d-3d46831e1817

The open-access MAF lists 169 somatic variants for this specimen: 108 protein-altering or splice-affecting, 43 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 43, Intron 9, Nonsense Mutation 8, Splice Site 5, 3'UTR 4, 5'Flank 3, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 74/578 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C11orf65 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs140854812; called by muse, mutect2
- C3 | c.2259G>C p.E753D | Missense Mutation (SNP) | VAF 71/471 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99837111; called by muse, mutect2, varscan2
- CACNA2D4 | c.3316G>A p.A1106T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1355042569; called by muse, varscan2
- CAMSAP3 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs773057926, COSV50368973; called by muse, mutect2, varscan2
- CAPN14 | c.1519G>C p.V507L | Missense Mutation (SNP) | VAF 48/493 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1484266596; called by muse, varscan2
- CBLIF | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); catalogued as rs760404861; called by muse, mutect2
- CCDC163 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 44/690 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs1440582490; called by muse, mutect2
- CENPF | c.5762T>C p.L1921P | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV65278912; called by muse, mutect2, varscan2
- DOCK11 | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52248281; called by muse, mutect2, varscan2
- DOCK7 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs1471015585; called by muse, mutect2, varscan2
- DZIP1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs1223899788; called by muse, mutect2
- EIF2AK3 | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 116/948 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs200955126; called by muse, mutect2, varscan2
- EPHA6 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101066243; called by muse, mutect2
- FBN2 | c.1432del p.A478Pfs*11 | Frame Shift Del (DEL) | VAF 35/304 reads (12%) | catalogued as COSV52538193; called by mutect2, pindel, varscan2
- FGFR1OP2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs144029112; called by muse, mutect2
- FLNC | c.6893C>A p.P2298H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1382734231; called by muse, mutect2
- GNL2 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 78/612 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66079753, COSV66081825; called by muse, mutect2, varscan2
- GOLGA8J | c.1682C>A p.A561D | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs909951916; called by muse, mutect2
- GPR158 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 65/587 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs771067011, COSV100893327; called by muse, mutect2, varscan2
- JAML | c.154A>G p.I52V (on ENST00000356289 / NM_001098526.2; = p.I42V on NM_153206.3) | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1446350744; called by muse, mutect2
- LRP11 | c.1308G>C p.K436N | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs760379286; called by muse, mutect2, varscan2
- MUC16 | c.37491G>T p.R12497S | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV101202192; called by muse, mutect2, varscan2
- OR3A1 | c.133A>G p.N45D | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60163513; called by muse, mutect2, varscan2
- OR8B4 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62070297; called by muse, mutect2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2
- PAN3 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101111174; called by muse, mutect2
- PCDHGB4 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs766365115, COSV53955001; called by muse, mutect2, varscan2
- PDGFRA | c.2986G>T p.E996* | Nonsense Mutation (SNP) | VAF 71/472 reads (15%) | catalogued as CM102817, COSV57269953; called by muse, mutect2, varscan2
- PRAMEF14 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 28/321 reads (9%) | catalogued as rs1232891746; called by muse, mutect2
- PTPRN2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs542709017; called by muse, mutect2
- RFPL1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.242); catalogued as rs765874853, COSV62977506; called by muse, mutect2, varscan2
- SIPA1L2 | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 71/612 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs745670783, COSV53384586; called by muse, mutect2, varscan2
- SYCP2 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV62769292; called by muse, mutect2
- TSC1 | c.989dup p.S331Efs*10 | Frame Shift Ins (INS) | VAF 74/609 reads (12%) | catalogued as rs118203478, CI992802; called by mutect2, pindel, varscan2
- ZNF32 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65641939; called by muse, mutect2, varscan2
- ZNF396 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1406870350; called by muse, mutect2
- ZNF442 | c.744T>G p.I248M | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV54423779; called by muse, mutect2
- ADCY6 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADGRE1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ADGRE2 | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- ANKRD26 | c.3807+1G>C p.X1269_splice | Splice Site (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- ANO2 | c.1417G>T p.E473* (on ENST00000356134 / NM_001278597.3; = p.E477* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 21/283 reads (7%) | called by muse, mutect2
- ARMH4 | c.2221C>G p.R741G | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP11A | c.3081G>A p.W1027* | Nonsense Mutation (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- CACNA1S | c.2551A>G p.M851V | Missense Mutation (SNP) | VAF 54/493 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CDH15 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CEP112 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 85/429 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP120 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CFAP61 | c.3151T>A p.Y1051N | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLVS1 | c.725A>C p.D242A | Missense Mutation (SNP) | VAF 14/371 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2
- CMTM4 | c.486_488del p.A163del | In Frame Del (DEL) | VAF 25/172 reads (15%) | called by mutect2, pindel, varscan2
- CRB1 | c.1474G>C p.G492R | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- DAG1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 108/955 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDB1 | c.549+7G>C | Splice Region (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- DENND4C | c.2914G>T p.D972Y (on ENST00000434457 / NM_001330640.2; = p.D923Y on NM_017925.7) | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DYSF | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.05); called by muse, varscan2
- FAM170B | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2
- FAT2 | c.6305A>G p.N2102S | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FBXO11 | c.2105A>G p.N702S (on ENST00000403359 / NM_001190274.2; = p.N618S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGA | c.2385G>A p.W795* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- FTHL17 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- GMNN | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GOLIM4 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- GYS2 | c.1268A>G p.D423G | Missense Mutation (SNP) | VAF 65/536 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- H1-4 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2
- KIAA1755 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- KRT85 | c.690+2T>A p.X230_splice | Splice Site (SNP) | VAF 25/388 reads (6%) | called by muse, mutect2
- LDB3 | c.2095-1G>A p.X699_splice | Splice Site (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- MAP4K4 | c.3274G>C p.A1092P (on ENST00000347699 / NM_001242559.2; = p.A1010P on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.884); called by muse, mutect2
- MDC1 | c.4036C>G p.P1346A | Missense Mutation (SNP) | VAF 50/467 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIA2 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- MIA2 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 32/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- MMP8 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYBL1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 55/535 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2
- MYO7B | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOC3L | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 84/669 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH3 | c.5853C>G p.N1951K | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG3 | c.1907T>A p.V636E (on ENST00000404547 / NM_001370084.1; = p.V612E on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/505 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- NTN1 | c.1237G>T p.G413C | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTN1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4A5 | c.587T>A p.V196D | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR8B3 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- PABPC5 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHC1 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 13/181 reads (7%) | called by muse, mutect2
- PI15 | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PORCN | c.1378A>G p.I460V (on ENST00000326194 / NM_203475.3; = p.I449V on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/573 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- PTPN3 | c.1069T>A p.S357T | Missense Mutation (SNP) | VAF 56/437 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- RALGAPA1 | c.5075G>A p.S1692N | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RPS17 | c.338G>C p.C113S | Missense Mutation (SNP) | VAF 114/973 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RUNDC3B | c.821A>G p.Q274R | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2
- RXFP3 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SCG3 | c.182-1G>A p.X61_splice | Splice Site (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- SCN3B | c.585-1G>C p.X195_splice | Splice Site (SNP) | VAF 19/555 reads (3%) | called by muse, mutect2
- SHROOM3 | c.664A>G p.S222G | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC49A3 | c.1438G>T p.A480S (on ENST00000404286 / NM_001294341.2; = p.A479S on NM_032219.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMYD2 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SSUH2 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- STARD6 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 49/400 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SUGCT | c.1237A>G p.K413E (on ENST00000335693 / NM_001193313.2; = p.K439E on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2
- SV2C | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); called by muse, mutect2
- TEX14 | c.2783G>T p.G928V (on ENST00000240361 / NM_001201457.2; = p.G922V on NM_031272.5) | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TEX14 | c.2782G>T p.G928* (on ENST00000240361 / NM_001201457.2; = p.G922* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- TIMM44 | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2
- TNIP1 | c.1822C>A p.P608T | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- TPGS2 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- USH2A | c.13456G>T p.V4486L | Missense Mutation (SNP) | VAF 54/570 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.357); called by muse, mutect2
- XIRP2 | c.6971G>T p.C2324F (on ENST00000628543; = p.C2499F on NM_152381.6) | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- AMER3 | c.1881C>G p.S627= | Silent (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- AZGP1 | c.444C>T p.N148= | Silent (SNP) | VAF 46/328 reads (14%) | called by muse, mutect2, varscan2
- BTBD3 | c.1296C>T p.G432= | Silent (SNP) | VAF 27/244 reads (11%) | catalogued as rs138082885; called by muse, mutect2, varscan2
- CELF3 | c.294T>C p.F98= | Silent (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- COMMD4 | c.312C>T p.A104= | Silent (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.39C>T p.V13= | Silent (SNP) | VAF 57/416 reads (14%) | called by muse, mutect2, varscan2
- DMXL2 | c.3813T>C p.Y1271= | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- EPHA4 | c.1830A>G p.R610= | Silent (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- FANCM | c.786G>T p.L262= | Silent (SNP) | VAF 79/618 reads (13%) | called by muse, mutect2, varscan2
- GDA | c.1362G>T p.V454= | Silent (SNP) | VAF 47/350 reads (13%) | called by muse, mutect2, varscan2
- GHRHR | c.828C>T p.D276= | Silent (SNP) | VAF 54/488 reads (11%) | catalogued as rs147768462; called by muse, mutect2
- GOLGA8J | c.1683C>T p.A561= | Silent (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- GRIK4 | c.2163C>A p.L721= | Silent (SNP) | VAF 43/312 reads (14%) | called by muse, mutect2, varscan2
- HDAC10 | c.855C>A p.L285= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- IFIT1B | c.63T>C p.F21= | Silent (SNP) | VAF 13/237 reads (5%) | catalogued as rs1018832402; called by muse, mutect2
- ITGA10 | c.1893G>T p.V631= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- KRTAP5-11 | c.57C>A p.S19= | Silent (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- LETM1 | c.1716G>A p.L572= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV100245530; called by muse, mutect2, varscan2
- LGALS9C | c.798C>G p.A266= | Silent (SNP) | VAF 56/332 reads (17%) | called by muse, mutect2, varscan2
- LRIT2 | c.726T>C p.F242= | Silent (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- LRP1B | c.4296G>T p.V1432= | Silent (SNP) | VAF 13/259 reads (5%) | catalogued as COSV67287590; called by muse, mutect2
- MAN2C1 | c.462G>T p.L154= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- MARK4 | c.936C>T p.I312= | Silent (SNP) | VAF 12/273 reads (4%) | catalogued as rs1193924070, COSV99488714; called by muse, mutect2
- MPO | c.2094A>T p.S698= | Silent (SNP) | VAF 85/522 reads (16%) | called by muse, mutect2, varscan2
- MSANTD2 | c.1164G>T p.L388= (on ENST00000374979 / NM_001308027.2; = p.L336= on NM_024631.4) | Silent (SNP) | VAF 21/308 reads (7%) | called by muse, mutect2
- OR2V1 | c.60C>G p.S20= | Silent (SNP) | VAF 30/228 reads (13%) | called by muse, mutect2, varscan2
- OR4K17 | c.624G>T p.L208= | Silent (SNP) | VAF 48/426 reads (11%) | catalogued as COSV59648408; called by muse, mutect2, varscan2
- OR5D13 | c.378G>T p.V126= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- PCARE | c.3843G>A p.Q1281= | Silent (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- PLEC | c.9769C>T p.L3257= (on ENST00000322810 / NM_201380.4; = p.L3147= on NM_000445.5) | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- POM121L2 | c.2799C>A p.I933= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV66276808; called by muse, mutect2
- PRDM14 | c.819T>C p.F273= | Silent (SNP) | VAF 25/487 reads (5%) | called by muse, mutect2
- PROS1 | c.1857G>T p.L619= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as COSV101260808; called by muse, mutect2
- SLC7A14 | c.2224C>A p.R742= | Silent (SNP) | VAF 16/275 reads (6%) | called by muse, mutect2
- SORCS3 | c.2166G>A p.K722= | Silent (SNP) | VAF 54/381 reads (14%) | catalogued as COSV63799210; called by muse, mutect2, varscan2
- SV2C | c.111C>A p.A37= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as COSV59231247; called by muse, mutect2
- TCF3 | c.1554G>A p.K518= | Silent (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- TECPR2 | c.72G>A p.P24= | Silent (SNP) | VAF 30/632 reads (5%) | catalogued as rs201004031, COSV104421938, COSV63974626; ClinVar: likely benign; called by muse, mutect2
- TRAV12-1 | c.27G>A p.V9= | Silent (SNP) | VAF 35/344 reads (10%) | called by muse, mutect2, varscan2
- TUBB4A | c.270C>T p.F90= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs369521667, COSV99899961, COSV99900193; called by muse, mutect2, varscan2
- UFL1 | c.1626A>G p.E542= | Silent (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- ZFHX4 | c.6222C>T p.D2074= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- ZNF205 | c.1470C>T p.H490= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- AGXT | c.847-138C>G | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846843 G>A | 5'Flank (SNP) | VAF 26/552 reads (5%) | catalogued as rs1158194938; called by muse, mutect2
- CAMKK1 | c.*4C>G | 3'UTR (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-4303C>A | Intron (SNP) | VAF 22/322 reads (7%) | catalogued as COSV64190457; called by muse, mutect2
- DCX | c.-22-409T>A | Intron (SNP) | VAF 73/668 reads (11%) | called by muse, mutect2, varscan2
- DIO1 | c.*14C>A | 3'UTR (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8557C>T | Intron (SNP) | VAF 20/329 reads (6%) | catalogued as rs571669209, COSV100876057; called by muse, mutect2
- HDLBP | c.1512+460C>G | Intron (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- MARCHF1 | c.242+851C>A | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2
- MOB2 | chr11:1469956 C>T | 3'Flank (SNP) | VAF 39/308 reads (13%) | called by muse, mutect2, varscan2
- NPAS3 | c.558+18039A>C | Intron (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- OR4C4P | n.474C>A | RNA (SNP) | VAF 81/601 reads (13%) | called by muse, mutect2, varscan2
- PLEC | c.524-5220C>G | Intron (SNP) | VAF 17/201 reads (8%) | called by muse, mutect2
- RBM33 | c.*20A>G | 3'UTR (SNP) | VAF 15/267 reads (6%) | called by muse, mutect2
- RNU6-389P | chr7:55685216 C>A | 5'Flank (SNP) | VAF 35/264 reads (13%) | called by muse, mutect2, varscan2
- RPL15P13 | chr10:114899539 C>A | 5'Flank (SNP) | VAF 28/257 reads (11%) | catalogued as rs1321068893; called by muse, mutect2, varscan2
- SCAPER | c.2838+6760C>G | Intron (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- TMTC2 | c.*4A>T | 3'UTR (SNP) | VAF 27/386 reads (7%) | called by muse, mutect2
